Gene-level copy-number profile of tumor specimen TCGA-28-5214-01A from TCGA case TCGA-28-5214, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.4 years (19,520 days).
Specimen TCGA-28-5214-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.b0cb2c90-240e-430a-bd51-4338eb666b26.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-28-5214-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/be1cf4b7-63e5-428e-b374-812481fdf285

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,941; copy number 2: 45,695; copy number 3: 6,972; copy number 4: 50; copy number 14: 59; copy number 24: 26; copy number 27: 12; copy number 29: 28; copy number 34: 14; copy number 35: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-28-5214-01A-01D-1479-01): tumor purity 0.76, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 161 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:242,671,140–245,709,432, 57 genes, copy number 14: AC099785.1, RSL24D1P4, AL445675.1, AL445675.2, AL603825.1, AL606534.3, SEPTIN14P21, CICP21, AL606534.4, LINC01347, RNU6-747P, CEP170, AL606534.1, AL606534.2, SDCCAG8, FCF1P7, MIR4677, AKT3, AL591721.1, FABP7P1, AL662889.1, AKT3-IT1, LINC02774, ZBTB18, AL590483.3, AL590483.1, AL590483.4, RN7SL148P, AL590483.2, AL358177.1, C1orf100, AL645465.1, TGIF2P1, ADSS2, CATSPERE, CYCSP5, DESI2, AL451007.1, AL451007.3, AL451007.2, BX323046.2, COX20, HNRNPU, BX323046.1, RN7SKP55, RNU6-947P, AL356512.1, EFCAB2, RNU6-1089P, RNU6-999P, AL589763.1, RNU1-132P, KIF26B, KIF26B-AS1, DNAJC19P8, AC104462.2, AC104462.1.
- chr1:246,025,897–246,113,866, 2 genes, copy number 14: AC118555.1, SMYD3-AS1.
- chr7:54,621,025–55,433,742, 14 genes, copy number 34 (within-gene range 3–34): RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2.
- chr12:57,738,013–58,395,138, 28 genes, copy number 29: TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1.
- chr12:58,920,639–59,789,855, 12 genes, copy number 35 (within-gene range 1–35): AC068305.2, RPS6P22, AC068305.1, AC046129.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P, SLC16A7, AC079905.2.
- chr12:62,643,994–62,935,150, 1 gene, copy number 27 (within-gene range 2–27): PPM1H.
- chr12:62,850,738–63,360,037, 11 genes, copy number 27: RNU1-83P, Y_RNA, RPL14P1, AC078814.2, LDHAL6CP, AC078814.1, RSL24D1P5, AVPR1A, AC135584.1, HNRNPA1P69, AC026116.1.
- chr12:68,746,125–68,971,570, 10 genes, copy number 35 (within-gene range 1–35): SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr20:10,435,305–12,381,255, 26 genes, copy number 24 (within-gene range 3–24): SLX4IP, AL035456.1, JAG1, MIR6870, AL050403.2, LINC01752, AL135937.1, AL050403.1, FAT1P1, LINC02871, AL158042.1, AL049649.1, RPS11P1, AL109837.2, AL109837.3, AL109837.1, PGAM3P, AL161938.1, LINC00687, RN7SKP111, AL080274.1, BTBD3, AL035448.1, AL109838.1, AL136460.1, PA2G4P2.

Autosomal genes at a single copy (total copy number 1): 4,555. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
